Somatic mutation profile of tumor specimen TCGA-69-7973-01A (aliquot TCGA-69-7973-01A-11D-2184-08) from TCGA case TCGA-69-7973, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 42.0 years (15,355 days).
Specimen TCGA-69-7973-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2d27836-615b-4573-ad60-5ff03edef8b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-7973-10A (Blood Derived Normal), aliquot TCGA-69-7973-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c28969c9-7e3a-4f87-aee0-83eadf2b8edd

The open-access MAF lists 279 somatic variants for this specimen: 215 protein-altering or splice-affecting, 57 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 57, Nonsense Mutation 19, Frame Shift Del 10, Splice Site 5, Splice Region 4, Frame Shift Ins 3, RNA 2, 3'UTR 2, Intron 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB5 | c.398C>G p.A133G | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.686); catalogued as COSV51720164; called by muse, mutect2, varscan2
- ABCB5 | c.1283G>T p.S428I | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs753417803, COSV99329509; called by muse, mutect2, varscan2
- ABCB5 | c.1759C>G p.R587G (on ENST00000404938 / NM_001163941.2; = p.R142G on NM_178559.6) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV51704222, COSV51720176; called by muse, mutect2, varscan2
- ABCG2 | c.1890C>A p.H630Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV52949243; called by muse, mutect2, varscan2
- AC011448.1 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 118/313 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52280125; called by muse, mutect2, varscan2
- ACSL1 | c.1683G>T p.K561N | Missense Mutation (SNP) | VAF 82/358 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55666309; called by muse, mutect2, varscan2
- ACSM2B | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 86/325 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61659846; called by muse, mutect2, varscan2
- ADAMTS12 | c.1838C>A p.T613N | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV61278161; called by muse, mutect2, varscan2
- ADCY10 | c.1985G>T p.R662L | Missense Mutation (SNP) | VAF 99/261 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as rs148745290, COSV63244648; called by muse, mutect2, varscan2
- AFF4 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.82); PolyPhen probably damaging (1); catalogued as rs1397950344, COSV54799554; called by muse, mutect2, varscan2
- AKAP4 | c.1948G>T p.E650* | Nonsense Mutation (SNP) | VAF 54/152 reads (36%) | catalogued as COSV100654102, COSV62075413; called by muse, mutect2, varscan2
- AMER3 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.43); catalogued as COSV58466900, COSV58468947; called by muse, mutect2, varscan2
- ANK2 | c.6267C>A p.S2089R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.034); catalogued as COSV52186755; called by muse, mutect2, varscan2
- ANKFN1 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); catalogued as COSV59455049; called by muse, mutect2, varscan2
- ARHGAP6 | c.1659C>G p.N553K | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57302916; called by muse, mutect2, varscan2
- ATP12A | c.2918G>T p.G973V | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54522880; called by muse, mutect2, varscan2
- C6orf136 | c.634C>T p.R212C (on ENST00000376473 / NM_001109938.3; = p.R78C on NM_145029.4) | Missense Mutation (SNP) | VAF 157/360 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1359767593, COSV53315954; called by muse, mutect2, varscan2
- CCDC136 | c.1272G>T p.K424N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV52804561; called by muse, mutect2, varscan2
- CCDC89 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV57034188; called by muse, mutect2, varscan2
- CD34 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212195813, COSV60414994; called by muse, mutect2, varscan2
- CDH12 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66444825; called by muse, mutect2, varscan2
- CDK8 | c.1150G>T p.G384* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV67423013; called by muse, mutect2, varscan2
- CES5A | c.280T>A p.C94S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51870385; called by muse, mutect2, varscan2
- CGN | c.2293G>T p.D765Y | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54973395; called by muse, mutect2, varscan2
- CHD5 | c.4946A>G p.D1649G | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV52424203; called by muse, mutect2, varscan2
- CLEC9A | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.179); catalogued as COSV59533940; called by muse, mutect2, varscan2
- CLPTM1 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61612999; called by muse, mutect2, varscan2
- COL20A1 | c.3655C>A p.P1219T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV100491399; called by muse, mutect2, varscan2
- COL22A1 | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.645); catalogued as rs369513330, COSV57329278; called by muse, mutect2, varscan2
- COL4A5 | c.3805G>T p.E1269* | Nonsense Mutation (SNP) | VAF 39/71 reads (55%) | catalogued as COSV60371224; called by muse, mutect2, varscan2
- COL6A2 | c.2421G>A p.P807= | Splice Region (SNP) | VAF 64/153 reads (42%) | catalogued as rs774494973, COSV56015504; called by muse, mutect2, varscan2
- COLEC11 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as COSV52597509; called by muse, mutect2, varscan2
- CREB3L2 | c.1174G>C p.G392R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57799870; called by muse, mutect2, varscan2
- CUBN | c.6655G>T p.G2219C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64726489; called by muse, mutect2, varscan2
- DACH1 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV57518560; called by muse, mutect2, varscan2
- DCDC1 | c.3344C>A p.P1115H (on ENST00000597505 / NM_001367979.1; = p.P222H on NM_020869.3) | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as COSV60312374; called by muse, mutect2, varscan2
- DDX43 | c.1306C>A p.R436S | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64813722; called by muse, mutect2, varscan2
- DHX34 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV60898025; called by muse, mutect2, varscan2
- DHX37 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs1483038765, COSV58139153; called by muse, mutect2, varscan2
- DICER1 | c.3578A>G p.N1193S | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1288723916, COSV58627616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH9 | c.6598G>T p.E2200* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as COSV52375173; called by muse, mutect2, varscan2
- DNPEP | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs780076462, COSV56111893; called by muse, mutect2, varscan2
- DOC2A | c.900C>A p.D300E | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58752621; called by muse, mutect2, varscan2
- DPY19L3 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as COSV60479916; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.785); catalogued as COSV50053640; called by muse, mutect2, varscan2
- DZIP1 | c.1853G>T p.S618I (on ENST00000347108; = p.S599I on NM_014934.5) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV61265062; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1360G>T p.E454* (on ENST00000361735 / NM_015935.5; = p.E368* on NM_014955.3) | Nonsense Mutation (SNP) | VAF 31/118 reads (26%) | catalogued as COSV62283755, COSV62283784; called by muse, mutect2, varscan2
- EFCAB6 | c.354C>A p.I118= | Splice Region (SNP) | VAF 19/143 reads (13%) | catalogued as COSV53072014; called by muse, mutect2, varscan2
- EMILIN3 | c.2267T>A p.L756Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV60037326; called by muse, mutect2, varscan2
- ENPP1 | c.1367G>T p.R456L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM031968, COSV62930765, COSV62936019; called by muse, mutect2, varscan2
- ERG | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs369318352; called by muse, mutect2, varscan2
- ERICH3 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1376721093, COSV58617424; called by muse, mutect2, varscan2
- FAM3D | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV62559491; called by muse, mutect2, varscan2
- FAM9B | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.788); catalogued as COSV59120350; called by muse, mutect2, varscan2
- FAT1 | c.7504G>A p.A2502T | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.243); catalogued as rs376062545; called by muse, mutect2, varscan2
- FBL | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 80/313 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV55683958; called by muse, mutect2, varscan2
- FCGR3B | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs375134752, COSV54211106; called by muse, mutect2, varscan2
- FCRLA | c.736T>A p.S246T (on ENST00000367959; = p.S223T on NM_032738.4) | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV52688276; called by muse, mutect2, varscan2
- FLT1 | c.3237G>T p.K1079N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV56741970; called by muse, mutect2, varscan2
- FOXR2 | c.532C>A p.Q178K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as COSV59259495, COSV59259634; called by muse, mutect2, varscan2
- FTHL17 | c.54C>A p.D18E | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63267198, COSV63267791; called by muse, mutect2, varscan2
- FUBP1 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV53938043; called by muse, mutect2, varscan2
- GAL3ST4 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV52785688; called by muse, mutect2, varscan2
- GAPDHS | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.923); catalogued as COSV55883807; called by muse, mutect2
- GAPDHS | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV55883818; called by muse, mutect2
- GJD2 | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV51749890, COSV51750479; called by muse, mutect2, varscan2
- GOT1 | c.823G>T p.G275* | Nonsense Mutation (SNP) | VAF 55/155 reads (35%) | catalogued as COSV65147956; called by muse, mutect2, varscan2
- GRHL2 | c.1518-1G>T p.X506_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as COSV52554353; called by muse, mutect2, varscan2
- GRIK2 | c.951G>A p.T317= | Splice Region (SNP) | VAF 19/81 reads (23%) | catalogued as COSV59769254; called by muse, mutect2, varscan2
- GRM3 | c.511T>A p.Y171N | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64479109; called by muse, mutect2, varscan2
- GSDMD | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV52798219; called by muse, mutect2, varscan2
- GSG1L | c.688T>C p.C230R (on ENST00000447459 / NM_001109763.2; = p.C75R on NM_144675.2) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV66582026; called by muse, mutect2, varscan2
- HDAC6 | c.2605A>T p.T869S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61930525; called by muse, mutect2, varscan2
- HFM1 | c.2680+1G>T p.X894_splice | Splice Site (SNP) | VAF 14/64 reads (22%) | catalogued as COSV54036569; called by muse, mutect2
- HFM1 | c.1159-2A>G p.X387_splice | Splice Site (SNP) | VAF 13/63 reads (21%) | catalogued as COSV54036577; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.385G>T p.G129* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV61256098; called by muse, mutect2, varscan2
- INSC | c.600C>A p.C200* | Nonsense Mutation (SNP) | VAF 30/109 reads (28%) | catalogued as rs1232975179, COSV65412992; called by muse, mutect2, varscan2
- ISOC1 | c.192G>T p.M64I | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV51492818; called by muse, mutect2, varscan2
- ITGA4 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as rs759443207, COSV52003758; called by muse, mutect2, varscan2
- ITGA8 | c.3155G>C p.R1052T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV65235434; called by muse, mutect2, varscan2
- ITGAX | c.2119G>C p.G707R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV51650226, COSV99192014; called by muse, mutect2, varscan2
- ITIH6 | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1028615038, COSV54494252; called by muse, mutect2, varscan2
- ITPR2 | c.4024G>T p.V1342L | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67275706; called by muse, mutect2, varscan2
- ITPR3 | c.1620G>T p.E540D | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV65414556; called by muse, mutect2, varscan2
- KCNC2 | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV54378849; called by muse, mutect2, varscan2
- KCNMB1 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.376); catalogued as COSV51135287; called by muse, mutect2, varscan2
- KIAA1210 | c.4457C>A p.S1486* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV68179972; called by muse, mutect2, varscan2
- KIAA1210 | c.3790T>C p.S1264P | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0.083); catalogued as COSV68179978; called by muse, mutect2, varscan2
- KLK15 | c.253C>A p.Q85K | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV56828459; called by muse, mutect2, varscan2
- LANCL3 | c.821G>T p.C274F | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV66130054; called by muse, mutect2, varscan2
- LCE2B | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs1274484732, COSV64228014; called by muse, mutect2, varscan2
- LCE3A | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV59551114; called by muse, mutect2, varscan2
- LIX1 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.047); catalogued as COSV57208202; called by muse, mutect2, varscan2
- LRP1B | c.6773G>A p.W2258* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV101260499, COSV67253870; called by muse, varscan2
- MACF1 | c.9311G>A p.S3104N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs769119415, COSV57142420; called by muse, mutect2, varscan2
- MACF1 | c.14768G>C p.W4923S (on ENST00000372915; = p.W2856S on NM_012090.5) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV57142432; called by muse, mutect2, varscan2
- MICAL2 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV56320252, COSV56325941; called by muse, mutect2, varscan2
- MICALL2 | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV52518653; called by muse, mutect2
- MSN | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.808); catalogued as COSV64305364; called by muse, mutect2, varscan2
- MUC16 | c.20282G>T p.R6761M | Missense Mutation (SNP) | VAF 99/203 reads (49%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.183); catalogued as COSV67467385; called by muse, varscan2
- NALCN | c.1017A>T p.R339S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.267); catalogued as COSV51963435; called by muse, mutect2, varscan2
- NBAS | c.5134A>T p.S1712C | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV55736832; called by muse, mutect2, varscan2
- NCAM1 | c.153C>A p.D51E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.02); catalogued as COSV100378523; called by muse, mutect2
- NCK2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1335454177, COSV51896084; called by muse, mutect2, varscan2
- NLRP5 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.234); catalogued as rs747631482, COSV66767167; called by muse, mutect2, varscan2
- NOL4 | c.1847A>T p.Y616F | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52360844; called by muse, mutect2, varscan2
- NOS1 | c.3868C>A p.Q1290K | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV57620948; called by muse, mutect2, varscan2
- NPAS4 | c.1024A>T p.M342L | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100215238; called by muse, mutect2, varscan2
- NPTX1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs377120879; called by muse, mutect2, varscan2
- NR5A2 | c.842C>A p.P281H (on ENST00000367362 / NM_205860.3; = p.P235H on NM_003822.5) | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.77); catalogued as COSV52657204; called by muse, mutect2, varscan2
- NRXN1 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as COSV101280477; called by muse, mutect2, varscan2
- NUP98 | c.4217C>T p.P1406L (on ENST00000359171 / NM_001365126.1; = p.P1389L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs768927481, COSV61434941; called by muse, mutect2, varscan2
- OR10H5 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100454794, COSV58277876; called by muse, mutect2, varscan2
- OR10H5 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100454796; called by muse, mutect2, varscan2
- OR1L3 | c.521T>A p.I174N | Missense Mutation (SNP) | VAF 117/209 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59170604; called by muse, mutect2, varscan2
- OR2A5 | c.507T>A p.C169* | Nonsense Mutation (SNP) | VAF 77/197 reads (39%) | catalogued as COSV68739115; called by muse, mutect2, varscan2
- OVCH1 | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV58967893; called by muse, mutect2, varscan2
- PAGE1 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV65998820; called by muse, mutect2, varscan2
- PAGE5 | c.43A>T p.R15W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56944516, COSV99215737; called by muse, mutect2, varscan2
- PALM | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.56); catalogued as COSV52770892, COSV52771013; called by muse, mutect2, varscan2
- PAPSS1 | c.1055G>T p.C352F | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54493059; called by muse, mutect2, varscan2
- PARD3B | c.2420C>G p.S807C (on ENST00000406610 / NM_001302769.2; = p.S738C on NM_057177.7) | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs753948335, COSV62529332; called by muse, mutect2, varscan2
- PATJ | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1406623318, COSV57171472; called by muse, mutect2, varscan2
- PCDH9 | c.3139-2A>T p.X1047_splice (on ENST00000377865 / NM_203487.3; = p.X1013_splice on NM_020403.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 5/17 reads (29%) | catalogued as COSV60576136, COSV60587820; called by muse, mutect2, varscan2
- PCDHB7 | c.1364C>A p.S455Y | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV99177342; called by muse, mutect2, varscan2
- PCDHGA2 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99541152; called by muse, mutect2, varscan2
- PDE10A | c.71T>A p.L24* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as COSV63105611; called by muse, mutect2
- PEX5L | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV55850848, COSV55856536; called by muse, mutect2, varscan2
- PIK3C2B | c.2443G>T p.D815Y | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV65814106; called by muse, mutect2, varscan2
- PIK3R5 | c.1828T>A p.Y610N | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52658430; called by muse, mutect2, varscan2
- PJVK | c.427A>T p.S143C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57870470; called by mutect2, varscan2
- PKHD1L1 | c.4349A>T p.Y1450F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV65740431, COSV65752151; called by muse, mutect2, varscan2
- PKP2 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV50747031; called by muse, varscan2
- PLPPR4 | c.1005G>C p.E335D | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV64564865, COSV64567621; called by muse, mutect2, varscan2
- POMT2 | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV55073802; called by muse, mutect2
- PORCN | c.742G>T p.A248S (on ENST00000326194 / NM_203475.3; = p.A237S on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as COSV58227138; called by muse, mutect2, varscan2
- POTEF | c.2148G>T p.M716I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.225); catalogued as COSV100665320; called by mutect2, varscan2
- PRRX1 | c.432C>A p.N144K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53418676; called by muse, mutect2, varscan2
- PRUNE2 | c.5785G>T p.D1929Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV65039084, COSV65047405; called by muse, mutect2, varscan2
- PTPN5 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.075); catalogued as rs1329371420, COSV62128457; called by muse, mutect2, varscan2
- PTPRF | c.3986A>T p.H1329L | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV63448630; called by muse, mutect2, varscan2
- PTPRN | c.2719G>T p.V907L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV55351990; called by muse, mutect2, varscan2
- PYROXD1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1168295317, COSV53711765; called by muse, mutect2, varscan2
- RBM19 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55698144; called by muse, mutect2, varscan2
- RCN3 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs774822949, COSV54543808; called by muse, mutect2, varscan2
- RP1L1 | c.2425C>A p.Q809K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV66759902; called by muse, mutect2, varscan2
- RRAGB | c.745G>T p.E249* (on ENST00000262850 / NM_016656.4; = p.E221* on NM_006064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV53331186, COSV53331680; called by muse, mutect2, varscan2
- RYR2 | c.1263C>A p.S421R | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.571); catalogued as COSV63711573; called by muse, mutect2, varscan2
- SACS | c.8704G>T p.G2902* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV66546505; called by muse, mutect2, varscan2
- SASH1 | c.2774C>G p.P925R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV66565573; called by muse, mutect2, varscan2
- SCARF2 | c.2006A>T p.K669M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56733867; called by muse, mutect2, varscan2
- SCGB1A1 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV53474008; called by muse, mutect2, varscan2
- SIRT7 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100155723; called by muse, mutect2, varscan2
- SLC15A1 | c.1408T>C p.Y470H | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.637); catalogued as COSV64733576; called by muse, mutect2, varscan2
- SLC4A11 | c.2560A>G p.M854V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.869); catalogued as rs373679606, COSV66263787; called by muse, mutect2, varscan2
- SLC6A5 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV54232087; called by muse, mutect2, varscan2
- SLC7A14 | c.1514A>T p.N505I | Missense Mutation (SNP) | VAF 131/235 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV51589486; called by muse, mutect2, varscan2
- SLIT2 | c.3900C>G p.N1300K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56593779; called by muse, mutect2, varscan2
- SMYD4 | c.2338G>C p.D780H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV54616973, COSV54617695; called by muse, mutect2, varscan2
- SORCS1 | c.1808C>A p.T603K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV53902539; called by muse, varscan2
- SPATA18 | c.1249A>G p.S417G | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV54649793; called by muse, mutect2
- SPEN | c.4194A>C p.L1398F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV65367227; called by muse, mutect2, varscan2
- STK36 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775486329, COSV55308546; called by muse, mutect2, varscan2
- TAS1R2 | c.1895G>T p.C632F | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV64747089; called by muse, mutect2, varscan2
- TENM4 | c.6617C>A p.S2206Y | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.991); catalogued as COSV53621166, COSV53666891; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2283G>T p.W761C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99305496; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2282G>T p.W761L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99305502; called by muse, mutect2, varscan2
- TGM6 | c.1448G>C p.R483P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as COSV52478921, COSV52483976; called by muse, mutect2, varscan2
- TMEM169 | c.420G>C p.R140S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as COSV55264912, COSV55266728; called by muse, mutect2, varscan2
- TTC29 | c.1242C>A p.N414K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57285199; called by muse, mutect2, varscan2
- TTC8 | c.1100G>T p.R367L (on ENST00000338104 / NM_001288781.1; = p.R351L on NM_144596.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57627864, COSV57630447; called by muse, mutect2, varscan2
- TTLL4 | c.2659C>T p.H887Y | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV51439249; called by muse, mutect2, varscan2
- UBQLN3 | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs769873541, COSV61165626; called by muse, mutect2, varscan2
- ULK4 | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV57222502; called by muse, varscan2
- VN1R4 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.317); catalogued as COSV100237584, COSV60805600; called by muse, mutect2, varscan2
- VSX1 | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV65022031, COSV65022221; called by muse, mutect2, varscan2
- WDPCP | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV55431926; called by muse, mutect2, varscan2
- WDR27 | c.783G>T p.Q261H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61215554; called by muse, varscan2
- WDR36 | c.1800T>A p.D600E | Missense Mutation (SNP) | VAF 71/315 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.914); catalogued as COSV72605477; called by muse, mutect2, varscan2
- WNT3A | c.332T>G p.F111C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52733741; called by muse, mutect2, varscan2
- WT1 | c.1387+7C>A | Splice Region (SNP) | VAF 69/253 reads (27%) | catalogued as COSV60082601; called by muse, mutect2, varscan2
- WWC3 | c.2061G>T p.Q687H | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV66507084; called by muse, mutect2, varscan2
- XKR7 | c.1229C>A p.T410N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV73813445; called by muse, mutect2, varscan2
- YLPM1 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); catalogued as COSV99461228; called by muse, mutect2, varscan2
- ZAP70 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774434467, COSV53856898; called by muse, mutect2, varscan2
- ZBBX | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV56800557; called by muse, mutect2, varscan2
- ZEB1 | c.500C>G p.S167* | Nonsense Mutation (SNP) | VAF 44/89 reads (49%) | catalogued as COSV58054028; called by muse, mutect2, varscan2
- ZFHX4 | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); catalogued as COSV50632102, COSV51494233; called by muse, mutect2, varscan2
- ZFHX4 | c.3361G>T p.D1121Y | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV51494245; called by muse, mutect2, varscan2
- ZFP69B | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV64316024; called by muse, mutect2, varscan2
- ZFPM2 | c.1734G>T p.M578I | Missense Mutation (SNP) | VAF 100/225 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs775101596, COSV65875695; called by muse, mutect2, varscan2
- ZNF519 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1257097651, COSV101645595; called by muse, mutect2, varscan2
- ZNF519 | c.1282G>T p.G428* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as COSV101645596; called by muse, mutect2, varscan2
- ZNF586 | c.1021G>T p.G341* | Nonsense Mutation (SNP) | VAF 35/121 reads (29%) | catalogued as COSV101197767, COSV66972737; called by muse, mutect2, varscan2
- ZNF605 | c.1834A>G p.T612A | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV59160030; called by muse, mutect2, varscan2
- ZNF622 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV58075145; called by muse, mutect2, varscan2
- ZNF808 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63121505; called by muse, mutect2, varscan2
- ZSWIM3 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54851226; called by muse, mutect2, varscan2
- AGO3 | c.1930del p.A644Pfs*43 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- C19orf44 | c.557del p.P186Lfs*33 | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | called by mutect2, pindel, varscan2
- CNTN2 | c.1300_1301del p.G434Rfs*49 | Frame Shift Del (DEL) | VAF 55/260 reads (21%) | called by mutect2, pindel, varscan2
- DGKK | c.615del p.R206Efs*9 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- GDF2 | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- HUWE1 | c.11728del p.H3910Tfs*14 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- LAMA3 | c.428_430delinsCC p.L143Pfs*15 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by pindel, varscan2*
- MON2 | c.2004del p.T669Qfs*2 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- PKP2 | c.138_139insA p.G47Rfs*39 | Frame Shift Ins (INS) | VAF 5/11 reads (45%) | called by muse*, mutect2
- PKP2 | c.136del p.R46Afs*66 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | called by muse*, mutect2, varscan2*
- POTEA | c.976-1G>A p.X326_splice (on ENST00000519951 / NM_001005365.2; = p.X280_splice on NM_001002920.1) | Splice Site (SNP) | VAF 40/119 reads (34%) | called by muse, mutect2, varscan2
- PTOV1 | c.1116_1122del p.K372Nfs*57 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- SLC6A20 | c.176del p.L59Cfs*70 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- TLN1 | c.5540_5542del p.E1847del | In Frame Del (DEL) | VAF 36/161 reads (22%) | called by mutect2, pindel, varscan2
- WDFY3 | c.5525dup p.L1842Ffs*52 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by mutect2, varscan2
- ZBTB16 | c.1168dup p.E390Gfs*26 | Frame Shift Ins (INS) | VAF 27/133 reads (20%) | called by mutect2, pindel, varscan2
- ACSM1 | c.1278G>A p.V426= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV54639793; called by muse, mutect2, varscan2
- ARID3C | c.1206C>A p.P402= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV52408980; called by muse, varscan2
- C2orf78 | c.171A>T p.A57= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV68519264; called by muse, mutect2, varscan2
- CAMTA1 | c.2055G>T p.T685= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs777218778, COSV100352294; called by muse, mutect2, varscan2
- CDH23 | c.8605C>T p.L2869= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV56487619; called by muse, mutect2, varscan2
- CDT1 | c.732G>T p.P244= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV56349755; called by muse, mutect2, varscan2
- CHL1 | c.960T>G p.T320= (on ENST00000397491 / NM_001253387.1; = p.T336= on NM_006614.4) | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as COSV56605460; called by muse, mutect2, varscan2
- COL26A1 | c.456G>T p.L152= (on ENST00000313669 / NM_001278563.3; = p.L150= on NM_133457.4) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV58131702; called by muse, mutect2, varscan2
- CTNNA2 | c.2514C>G p.T838= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- DPPA2 | c.840C>A p.P280= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV72118309, COSV72118314; called by muse, mutect2, varscan2
- ERBB4 | c.633G>A p.T211= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as rs142765774; called by muse, mutect2, varscan2
- FREM1 | c.4257T>A p.A1419= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV101085406; called by muse, mutect2, varscan2
- GAB4 | c.897C>T p.H299= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV68755157; called by muse, mutect2, varscan2
- GAL3ST2 | c.186G>T p.T62= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV51951580; called by muse, mutect2, varscan2
- GALNT2 | c.453C>G p.A151= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs754471301, COSV64197334; called by muse, mutect2, varscan2
- GFRA2 | c.126G>A p.R42= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- HIRIP3 | c.1200T>A p.S400= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV54231695; called by muse, mutect2, varscan2
- HMCN1 | c.13074C>T p.N4358= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as COSV54938615; called by muse, mutect2, varscan2
- ITGAX | c.2118C>T p.L706= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs181623963, COSV99191883; called by muse, mutect2, varscan2
- KCNJ4 | c.39C>A p.P13= | Silent (SNP) | VAF 139/309 reads (45%) | catalogued as rs1445446583, COSV57858640; called by muse, mutect2, varscan2
- LMTK3 | c.148C>T p.L50= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1174494790; called by muse, mutect2
- MISP | c.1770C>A p.S590= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV53122187; called by muse, mutect2, varscan2
- MYT1L | c.2010C>A p.P670= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV67710165, COSV67731728; called by muse, mutect2, varscan2
- NID2 | c.1083G>A p.L361= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV53502446; called by muse, mutect2, varscan2
- NPAS4 | c.1023C>A p.T341= | Silent (SNP) | VAF 65/221 reads (29%) | catalogued as COSV100215235; called by muse, mutect2, varscan2
- OR10S1 | c.717G>A p.V239= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV73343026; called by muse, mutect2, varscan2
- OR14C36 | c.549G>A p.L183= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as COSV58600364, COSV58601616; called by muse, mutect2, varscan2
- OR5B2 | c.780C>A p.P260= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV56909546; called by muse, mutect2, varscan2
- PCDHB7 | c.1365C>T p.S455= | Silent (SNP) | VAF 65/172 reads (38%) | catalogued as rs781999595, COSV99177343; called by muse, mutect2, varscan2
- PCDHGB6 | c.844C>A p.R282= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV53897747, COSV54025291; called by muse, mutect2, varscan2
- PCYT1B | c.9C>A p.G3= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV64778667; called by muse, mutect2, varscan2
- PDE2A | c.1542C>T p.V514= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV57813141; called by muse, mutect2, varscan2
- PDP1 | c.558G>T p.L186= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs926037932, COSV52603755; called by muse, mutect2, varscan2
- PKD1L2 | c.102C>A p.A34= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV61419372; called by muse, mutect2, varscan2
- POPDC3 | c.435C>A p.A145= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV54646104; called by muse, mutect2, varscan2
- PRPF40A | c.2445A>G p.P815= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV68359231; called by muse, mutect2, varscan2
- PSTPIP1 | c.912C>A p.S304= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV51207368; called by muse, varscan2
- PTPRF | c.21A>T p.P7= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV63448626; called by muse, mutect2, varscan2
- SERPINB3 | c.318G>A p.K106= | Silent (SNP) | VAF 55/131 reads (42%) | catalogued as COSV52194006; called by muse, mutect2, varscan2
- SIX3 | c.834C>T p.S278= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99578555; called by muse, mutect2
- SLAMF9 | c.807G>A p.K269= | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as COSV100928142, COSV100928186, COSV63637247; called by muse, mutect2, varscan2
- SLC8A3 | c.441G>A p.E147= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV63526208; called by muse, mutect2, varscan2
- SPINK7 | c.132C>A p.P44= | Silent (SNP) | VAF 79/173 reads (46%) | catalogued as COSV51001853; called by muse, mutect2, varscan2
- STON2 | c.2247G>A p.T749= (on ENST00000649389 / NM_001366849.2; = p.T692= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/216 reads (38%) | catalogued as rs1299030093, COSV50854112; called by muse, mutect2, varscan2
- SUCLG2 | c.339G>T p.V113= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV56211894; called by muse, mutect2, varscan2
- SULF1 | c.867G>T p.V289= | Silent (SNP) | VAF 97/209 reads (46%) | catalogued as COSV52692387; called by muse, mutect2, varscan2
- SUPT20HL1 | c.2202G>T p.T734= | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- TBX5 | c.1056C>A p.S352= | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as COSV59864992; called by muse, mutect2, varscan2
- TMC2 | c.2175G>T p.P725= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV62657925; called by muse, mutect2, varscan2
- TMC3 | c.2406T>A p.P802= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV63924569; called by muse, mutect2, varscan2
- TMTC4 | c.1587G>A p.R529= (on ENST00000376234 / NM_001350577.2; = p.R548= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV60893488; called by muse, mutect2, varscan2
- TNFRSF11B | c.105C>G p.T35= | Silent (SNP) | VAF 71/267 reads (27%) | catalogued as COSV52073637, COSV52073909; called by muse, mutect2, varscan2
- TNXB | c.12226C>A p.R4076= (on ENST00000647633; = p.R3829= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as COSV64481969, COSV64488276; called by muse, mutect2, varscan2
- TRIM35 | c.558G>T p.R186= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV59522637; called by muse, mutect2, varscan2
- XIRP2 | c.6255C>A p.S2085= (on ENST00000628543; = p.S2260= on NM_152381.6) | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV54731966; called by muse, mutect2, varscan2
- ZNF770 | c.1629C>T p.N543= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV62545001; called by muse, mutect2, varscan2
- ZSCAN18 | c.1020C>T p.D340= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1473135166, COSV53736089; called by muse, mutect2, varscan2
- AP2A2 | c.*730A>T | 3'UTR (SNP) | VAF 9/12 reads (75%) | catalogued as COSV100173314; called by muse, mutect2, varscan2
- FBXL21P | n.1256C>G | RNA (SNP) | VAF 14/71 reads (20%) | catalogued as COSV51810032; called by muse, mutect2, varscan2
- N4BP2L1 | c.474-513C>T | Intron (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21172466 T>A | 5'Flank (SNP) | VAF 11/47 reads (23%) | catalogued as COSV68841277; called by muse, mutect2, varscan2
- USH1C | c.1285-7583C>A | Intron (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99141904; called by muse, mutect2, varscan2
- WASF4P | n.1141C>A | RNA (SNP) | VAF 18/45 reads (40%) | called by muse, varscan2
- ZNF99 | c.*188C>A | 3'UTR (SNP) | VAF 27/89 reads (30%) | catalogued as COSV68056644; called by muse, mutect2
